CPTAC case SC-0439 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bb3a690c-021d-4375-9bfd-efd09c1449d5

Demographics
Sex at birth: male; Vital status: Alive.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of other and unspecified parts of face; Age at diagnosis: 79.0 years (28,855 days); AJCC staging edition: 8th; AJCC pathologic T: T4b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIC; Progression or recurrence: no; Days to last follow up: 761 days (2.1 years); Clark level: IV.
   Pathology details: Breslow thickness: 8.8.

Biospecimens (1 sample)
- Sample S-1903-009523: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Frozen; Initial weight: 192 mg; Method of sample procurement: Tumor Resection.
